Somatic mutation profile of tumor specimen TCGA-44-6146-01A (aliquot TCGA-44-6146-01A-21D-A27T-08) from TCGA case TCGA-44-6146, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Mucinous adenocarcinoma; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IIB; Age at diagnosis: 64.0 years (23,378 days).
Specimen TCGA-44-6146-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) be898971-7e06-4c41-a5ab-cae1860a19fb.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-44-6146-10A (Blood Derived Normal), aliquot TCGA-44-6146-10A-01D-1753-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6a815cf2-e7f7-4e6b-b93a-6f4c562835bf

The open-access MAF lists 46 somatic variants for this specimen: 36 protein-altering or splice-affecting, 10 silent.
By variant classification: Missense Mutation 28, Silent 10, Nonsense Mutation 6, In Frame Del 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>T p.G12V | Missense Mutation (SNP) | VAF 5/20 reads (25%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ABCB11 | c.493A>C p.I165L | Missense Mutation (SNP) | VAF 19/62 reads (31%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV99791454; called by muse, mutect2, varscan2
- AC013477.1 | c.2491A>T p.R831W | Missense Mutation (SNP) | VAF 13/64 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.993); catalogued as COSV99548685; called by muse, mutect2, varscan2
- ADH4 | c.152C>A p.A51D | Missense Mutation (SNP) | VAF 29/96 reads (30%) | SIFT tolerated (0.34); PolyPhen benign (0.001); catalogued as COSV99643937, COSV99643982; called by muse, mutect2, varscan2
- ASTN1 | c.1051A>G p.T351A | Missense Mutation (SNP) | VAF 13/38 reads (34%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.003); catalogued as COSV56090478; called by muse, mutect2, varscan2
- B4GAT1 | c.514G>A p.E172K | Missense Mutation (SNP) | VAF 15/37 reads (41%) | SIFT tolerated (0.41); PolyPhen benign (0.044); catalogued as COSV60820821, COSV60820969; called by muse, mutect2, varscan2
- C20orf194 | c.1888C>G p.L630V | Missense Mutation (SNP) | VAF 49/158 reads (31%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.99); catalogued as COSV52704785; called by muse, mutect2, varscan2
- CLSPN | c.2659T>C p.Y887H | Missense Mutation (SNP) | VAF 37/122 reads (30%) | SIFT tolerated (0.1); PolyPhen benign (0.024); catalogued as COSV52058231; called by muse, mutect2, varscan2
- CSAD | c.625C>T p.R209* (on ENST00000444623 / NM_001244705.2; = p.R236* on NM_015989.5) | Nonsense Mutation (SNP) | VAF 31/109 reads (28%) | catalogued as rs868842768, COSV99914450; called by muse, mutect2, varscan2
- DCT | c.250G>T p.E84* | Nonsense Mutation (SNP) | VAF 36/133 reads (27%) | catalogued as COSV65471069; called by muse, mutect2, varscan2
- DISC1 | c.1172A>G p.H391R | Missense Mutation (SNP) | VAF 34/122 reads (28%) | SIFT tolerated (0.67); PolyPhen benign (0.09); catalogued as rs1303682098, COSV54421512; called by muse, mutect2, varscan2
- FBXO15 | c.1476C>G p.N492K | Missense Mutation (SNP) | VAF 12/160 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.036); catalogued as COSV99502983; called by muse, mutect2
- FCSK | c.1147G>A p.V383I | Missense Mutation (SNP) | VAF 8/16 reads (50%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.483); catalogued as rs376461962; called by muse, mutect2, varscan2
- IGSF1 | c.1142A>T p.N381I | Missense Mutation (SNP) | VAF 36/55 reads (65%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.664); catalogued as COSV63841030; called by muse, mutect2, varscan2
- KCNJ8 | c.137C>T p.A46V | Missense Mutation (SNP) | VAF 35/121 reads (29%) | SIFT tolerated (0.64); PolyPhen probably damaging (0.999); catalogued as rs1565662161, COSV53718625; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- LPP | c.1243C>T p.R415C | Missense Mutation (SNP) | VAF 12/64 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.872); catalogued as rs756437011, COSV57080914; called by muse, mutect2, varscan2
- MAP3K7 | c.869A>G p.Y290C | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT tolerated (0.09); PolyPhen benign (0.043); catalogued as COSV65226366; called by muse, mutect2, varscan2
- NKX2-1 | c.236C>A p.S79* | Nonsense Mutation (SNP) | VAF 13/30 reads (43%) | catalogued as CM146079, COSV100701734, COSV61390068; called by muse, mutect2, varscan2
- NKX2-5 | c.187G>T p.A63S | Missense Mutation (SNP) | VAF 13/22 reads (59%) | SIFT tolerated (0.77); PolyPhen benign (0.003); catalogued as COSV61300174; called by muse, mutect2, varscan2
- NTM | c.184C>T p.R62W | Missense Mutation (SNP) | VAF 26/76 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.935); catalogued as rs1349372881, COSV66190799; called by mutect2, varscan2
- OR2T27 | c.61G>A p.A21T | Missense Mutation (SNP) | VAF 15/113 reads (13%) | SIFT tolerated (0.64); PolyPhen benign (0); catalogued as rs1363068542, COSV61283144; called by muse, mutect2, varscan2
- PLPP7 | c.697G>A p.G233S | Missense Mutation (SNP) | VAF 21/71 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.908); catalogued as rs148777558; called by muse, mutect2, varscan2
- REV1 | c.134C>A p.S45* | Nonsense Mutation (SNP) | VAF 38/138 reads (28%) | catalogued as COSV51487547, COSV51491561; called by muse, mutect2, varscan2
- RFESD | c.332G>A p.C111Y | Missense Mutation (SNP) | VAF 27/57 reads (47%) | SIFT tolerated (1); PolyPhen possibly damaging (0.677); catalogued as COSV99174125; called by muse, mutect2, varscan2
- RYR2 | c.3974C>A p.A1325D | Missense Mutation (SNP) | VAF 30/116 reads (26%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as COSV100769031, COSV63692287; called by muse, mutect2, varscan2
- RYR2 | c.8443G>T p.V2815L | Missense Mutation (SNP) | VAF 9/23 reads (39%) | SIFT tolerated (0.5); PolyPhen benign (0.001); catalogued as COSV63721083; called by muse, mutect2, varscan2
- SAFB | c.1925G>A p.R642H | Missense Mutation (SNP) | VAF 20/90 reads (22%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.972); catalogued as rs772893143, COSV52654750; called by muse, mutect2, varscan2
- SLC22A7 | c.212G>A p.R71Q | Missense Mutation (SNP) | VAF 28/75 reads (37%) | SIFT tolerated (0.35); PolyPhen benign (0.107); catalogued as rs781251888, COSV101000735, COSV65356964; called by muse, mutect2, varscan2
- SYBU | c.904C>T p.L302F (on ENST00000276646 / NM_001099754.2; = p.L301F on NM_017786.6) | Missense Mutation (SNP) | VAF 29/88 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV52624057; called by muse, mutect2, varscan2
- TENM1 | c.1613G>A p.G538E | Missense Mutation (SNP) | VAF 22/37 reads (59%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.465); catalogued as COSV64447099; called by muse, mutect2, varscan2
- UNC5B | c.871C>T p.Q291* | Nonsense Mutation (SNP) | VAF 29/89 reads (33%) | catalogued as COSV58982229; called by muse, mutect2, varscan2
- WAC | c.1375C>T p.Q459* | Nonsense Mutation (SNP) | VAF 49/133 reads (37%) | catalogued as COSV61567752, COSV61570303; called by muse, mutect2, varscan2
- XKR7 | c.868G>A p.D290N | Missense Mutation (SNP) | VAF 20/50 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.701); catalogued as rs778957299, COSV73813534; called by muse, mutect2, varscan2
- CCL15 | c.175T>C p.S59P | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT tolerated (0.97); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- CORO1C | c.458_476del p.N153Mfs*9 | Frame Shift Del (DEL) | VAF 10/106 reads (9%) | called by mutect2, pindel
- MAP3K12 | c.868_870del p.K290del | In Frame Del (DEL) | VAF 47/167 reads (28%) | called by mutect2, pindel, varscan2
- ADH4 | c.153C>A p.A51= | Silent (SNP) | VAF 29/96 reads (30%) | catalogued as COSV99643979; called by muse, mutect2, varscan2
- CDH9 | c.888C>T p.D296= | Silent (SNP) | VAF 70/208 reads (34%) | catalogued as rs373803020, COSV99157258; called by muse, mutect2, varscan2
- GABRG3 | c.918C>T p.S306= | Silent (SNP) | VAF 27/91 reads (30%) | catalogued as COSV61538285; called by muse, mutect2, varscan2
- GRIN2C | c.1419C>T p.Y473= | Silent (SNP) | VAF 87/275 reads (32%) | catalogued as rs746853533, COSV53117747; called by muse, mutect2, varscan2
- HGSNAT | c.720C>T p.L240= | Silent (SNP) | VAF 4/12 reads (33%) | catalogued as COSV65536076; called by mutect2, varscan2
- KIDINS220 | c.1986C>T p.I662= | Silent (SNP) | VAF 21/84 reads (25%) | catalogued as COSV56760683; called by muse, mutect2, varscan2
- NMUR1 | c.903C>T p.V301= | Silent (SNP) | VAF 26/77 reads (34%) | catalogued as rs138820733; called by muse, mutect2, varscan2
- SIAH3 | c.651G>A p.T217= | Silent (SNP) | VAF 31/87 reads (36%) | catalogued as rs758362830, COSV68553686; called by muse, mutect2, varscan2
- TIMELESS | c.1224C>T p.F408= | Silent (SNP) | VAF 46/136 reads (34%) | catalogued as COSV57516164; called by muse, mutect2, varscan2
- USP6NL | c.2445G>A p.R815= | Silent (SNP) | VAF 23/85 reads (27%) | catalogued as COSV53216826; called by muse, mutect2, varscan2
